Gene-level copy-number profile of tumor specimen HCM-WCMC-1359-C34-01A from HCMI case HCM-WCMC-1359-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 60.5 years (22,094 days).
Specimen HCM-WCMC-1359-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file adc36e09-e6f8-44e8-ab0f-5ae80e6e7302.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1359-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/24b2c500-2904-4d9c-adfa-e9efaae827b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 207; copy number 1: 10,307; copy number 2: 43,860; copy number 3: 4,327; copy number 4: 57; copy number 5: 13; copy number 10: 96; copy number 12: 33; copy number 16: 3.

Homozygous deletions (total copy number 0; autosomes only): 207 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,700,595–8,797,194, 3 genes (within-gene range 0–1): AL583805.2, AL583805.1, RNU7-185P.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.
- chr22:21,759,657–23,145,021, 145 genes (within-gene range 0–1) (broad region; genes not listed).
- chr22:23,179,704–24,178,628, 58 genes (within-gene range 0–1): BCR, BCRP8, RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3, AP000346.1, GUSBP11, AP000346.2, ASLP1, AP000347.1, RGL4, ZNF70, VPREB3, C22orf15, CHCHD10, MMP11, SMARCB1, DERL3, AP000350.5, SLC2A11, AP000350.4, AP000350.8, RN7SL268P, MIF, MIF-AS1, AP000350.6, AP000350.2, AP000350.1, AP000350.3, GSTT2B, AC253536.2, DDTL, AC253536.6, DDT, AC253536.7, AC253536.1, AC253536.5, GSTT2, GSTT4, AC253536.4, CABIN1, AC253536.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 145 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:27,779,821–27,781,067, 1 gene, copy number 5 (within-gene range 3–5): AC009511.2.
- chr22:17,036,570–17,258,235, 12 genes, copy number 5 (within-gene range 4–5): CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1, ADA2, AC005300.1, FAM32BP.
- chr22:18,636,445–18,719,341, 3 genes, copy number 16: CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:19,667,023–21,735,794, 129 genes, copy number 10–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,613. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
